Gene-level copy-number profile of tumor specimen TCGA-A6-A56B-01A from TCGA case TCGA-A6-A56B, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 57.2 years (20,903 days).
Specimen TCGA-A6-A56B-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.bc4b1704-3772-4467-8bb3-8e99ea93657c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-A6-A56B-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b94abaf9-7da3-4bab-89ed-f9586417c0e6

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 2,090; copy number 2: 12,162; copy number 3: 32,056; copy number 4: 6,777; copy number 5: 3,470; copy number 6: 1,330; copy number 7: 1,376; copy number 8: 380; copy number 9: 56; copy number 10: 120.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-A6-A56B-01A-31D-A28F-01): tumor purity 0.72, ploidy 3.21, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,932 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:485,154–28,410,456, 589 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr7:38,256,337–38,311,808, 9 genes, copy number 10: TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1.
- chr11:12,674,421–43,920,944, 436 genes, copy number 8–9 (within-gene range 4–9) (broad region; genes not listed).
- chr11:44,260,440–46,177,106, 45 genes, copy number 7: ALX4, AC010768.4, AC010768.3, CD82, AC010768.1, AC010768.2, RPL34P22, AC104010.1, LINC02704, TSPAN18-AS1, TSPAN18, TP53I11, LINC02685, AC068858.1, PRDM11, AC103681.2, SYT13, AC103681.1, LINC02696, LINC02687, AC103855.3, AC018716.2, AC018716.1, AC103855.2, AC103855.4, AC103855.1, CHST1, AC087442.1, MIR7154, AC044839.1, AC044839.2, LINC02690, LINC02716, SLC35C1, AC044839.3, CRY2, MAPK8IP1, AC068385.1, C11orf94, PEX16, LARGE2, PHF21A, AC024475.1, AC024475.3, AC024475.2.
- chr13:55,062,945–56,216,942, 7 genes, copy number 7: LINC02335, AL139038.1, MIR5007, AL354821.1, HNF4GP1, AL138997.1, SPATA2P1.
- chr20:32,005,671–64,313,132, 846 genes, copy number 7–10 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,588. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
